TCGA case TCGA-23-1114 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c0c3caab-9277-4a31-a96c-c607e38d5ccc

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Dead; Days to death: 2,089 days (5.7 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 55.9 years (20,409 days); Year of diagnosis: 2000; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: No macroscopic disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 43 days; Days to treatment end: 182 days; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 663 days (1.8 years); Days to treatment end: 747 days (2.0 years); Number of cycles: 5; Treatment dose: 2,100 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 663 days (1.8 years); Days to treatment end: 747 days (2.0 years); Number of cycles: 5; Treatment dose: 1,400 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Consolidation Therapy; Days to treatment start: 865 days (2.4 years); Days to treatment end: 907 days (2.5 years); Number of cycles: 3; Treatment dose: 1,305 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,159 days (3.2 years); Days to treatment end: 1,222 days (3.3 years); Number of cycles: 4; Treatment dose: 520 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Persistent Disease; Days to treatment start: 1,324 days (3.6 years); Days to treatment end: 1,350 days (3.7 years); Number of cycles: 2; Treatment dose: 260 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Persistent Disease; Days to treatment start: 1,324 days (3.6 years); Days to treatment end: 1,350 days (3.7 years); Number of cycles: 2; Treatment dose: 5,500 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Persistent Disease; Days to treatment start: 1,348 days (3.7 years); Days to treatment end: 1,425 days (3.9 years); Number of cycles: 3; Treatment dose: 9,625 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Persistent Disease; Days to treatment start: 1,357 days (3.7 years); Days to treatment end: 1,425 days (3.9 years); Number of cycles: 3; Treatment dose: 1,190 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 1,741 days (4.8 years); Days to treatment end: 1,918 days (5.3 years); Number of cycles: 7; Treatment dose: 475 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 1,985 days (5.4 years); Days to treatment end: 2,026 days (5.5 years); Number of cycles: 6; Treatment dose: 20 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 57.6 years (21,043 days); Days to diagnosis: 634 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 634 days (1.7 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 634 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 634 days (1.7 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 2,089 days (5.7 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Evidence of progression type: Convincing Image Source; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-23-1114-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-23-1114-01B-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
  Slide TCGA-23-1114-01B-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
- Sample TCGA-23-1114-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-23-1114-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Anatomic organ subdivision: Left; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Consolidation.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Therapy regimen: Progression.
- Drug treatment 3: Pharmaceutical therapy drug name: Doxil.
- Drug treatment 6: Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Persistent.
- Drug treatment 8: Pharmaceutical therapy drug name: Gemzar; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Persistent.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,089 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,089 days; disease-free interval: event (new tumor event after initially disease-free), 634 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 634 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-23-1114-01B-01D-0559-01): tumor purity 0.76, ploidy 4.19, whole-genome doublings 2.
